Somatic mutation profile of tumor specimen MP2PRT-PATDVP-TMP1-A (aliquot MP2PRT-PATDVP-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATDVP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (693 days).
Specimen MP2PRT-PATDVP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1161caef-508b-4a8e-b548-47c5a7a219fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDVP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDVP-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6d15fe4-d0ab-47d4-a28b-7cb70048545e

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNC | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 124/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs387906587, CM114108, COSV57967712; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CCN4 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs374293123, COSV51532871; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- MAP3K12 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 261/564 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374436740; called by muse, mutect2, varscan2
- MTOR | c.4348T>G p.Y1450D | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63868148; called by muse, mutect2, varscan2
- PSENEN | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 254/566 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs746209639, COSV53074151, COSV99495147; called by muse, mutect2, varscan2
- PXDNL | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 161/418 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs747609078, COSV62480011; called by muse, mutect2, varscan2
- ADCY7 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN2A | c.190_205del p.L64Sfs*77 | Frame Shift Del (DEL) | VAF 156/254 reads (61%) | called by pindel, varscan2
- DDX55 | c.1242C>G p.D414E | Missense Mutation (SNP) | VAF 76/417 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- HYDIN | c.14018C>T p.P4673L | Missense Mutation (SNP) | VAF 71/618 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PCDHB15 | c.1999T>G p.S667A | Missense Mutation (SNP) | VAF 354/828 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SLC4A5 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SPINT3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TRIML2 | c.473T>G p.M158R | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- GRPR | c.399G>A p.A133= | Silent (SNP) | VAF 182/428 reads (43%) | catalogued as rs1299617422, COSV66669612; called by muse, mutect2, varscan2
- LAMA5 | c.3591G>A p.P1197= | Silent (SNP) | VAF 260/583 reads (45%) | catalogued as rs151262272; called by muse, mutect2, varscan2
- LYSMD4 | c.558T>C p.F186= (on ENST00000409796 / NM_001284417.2; = p.F187= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/429 reads (28%) | called by muse, mutect2, varscan2
- NRAS | c.183A>G p.Q61= | Silent (SNP) | VAF 165/419 reads (39%) | catalogued as COSV54736320, COSV54736991, COSV54744813; called by muse, mutect2
- TMEM94 | c.3688C>T p.L1230= | Silent (SNP) | VAF 185/435 reads (43%) | called by muse, mutect2, varscan2
